Somatic mutation profile of tumor specimen TCGA-99-AA5R-01A (aliquot TCGA-99-AA5R-01A-11D-A397-08) from TCGA case TCGA-99-AA5R, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.6 years (25,778 days).
Specimen TCGA-99-AA5R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02b85206-3f54-4b9d-8a11-e0d5ddaad387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-AA5R-10A (Blood Derived Normal), aliquot TCGA-99-AA5R-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84cb2e34-c26d-459c-bf13-c94ca34cdc8e

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Nonsense Mutation 3, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.3496C>T p.R1166* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as rs368794890; called by muse, mutect2
- ACAP2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100462600; called by muse, mutect2
- ACTL6B | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99355712; called by muse, mutect2
- ADAMTS5 | c.2525C>A p.P842Q | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs1433926310, COSV99538181; called by muse, mutect2
- BPIFC | c.979-1G>T p.X327_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100301222; called by muse, mutect2, varscan2
- CD55 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1417862872, COSV100132630; called by muse, mutect2
- CDH6 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99420168, COSV99420502; called by muse, mutect2
- CHML | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100086851; called by muse, mutect2, varscan2
- COL3A1 | c.4234G>C p.V1412L | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100483615; called by muse, mutect2
- CRNKL1 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as COSV99846286; called by muse, mutect2
- CTNNA2 | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100785650; called by muse, mutect2
- DBX2 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV60339099; called by muse, mutect2
- FAM47C | c.2815G>T p.G939* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV100792271, COSV63730525; called by muse, mutect2
- IFT140 | c.1889A>T p.Q630L | Missense Mutation (SNP) | VAF 6/215 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101276584; called by muse, mutect2
- IFT140 | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 6/218 reads (3%) | catalogued as COSV101276585, COSV68493411; called by muse, mutect2
- IGSF1 | c.2459G>T p.S820I | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100812267; called by muse, mutect2
- KIFC1 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997132; called by muse, mutect2
- KLF12 | c.1056A>T p.E352D | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.048); catalogued as COSV66569998; called by muse, mutect2
- LCE3B | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100167535; called by muse, mutect2
- MPPED2 | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV100813491, COSV63898371; called by muse, mutect2
- NCAPD3 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV101596376; called by muse, mutect2, varscan2
- NLRP10 | c.1763T>A p.I588K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV100149915; called by muse, mutect2
- NOVA1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948475; called by muse, mutect2
- NR5A2 | c.594G>T p.Q198H (on ENST00000367362 / NM_205860.3; = p.Q152H on NM_003822.5) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99371539; called by muse, mutect2
- RIMS2 | c.4160G>T p.R1387L (on ENST00000666250 / NM_001348490.2; = p.R958L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV51701704, COSV51716984, COSV51738445; called by muse, mutect2
- RIOX1 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100408088; called by muse, mutect2
- SLAMF8 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99223079; called by muse, mutect2
- SLCO6A1 | c.265T>A p.C89S | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.622); catalogued as COSV101134842; called by muse, mutect2
- STAP1 | c.792A>T p.L264F | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99609612; called by muse, mutect2
- TNRC6B | c.1714C>G p.Q572E | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.759); catalogued as COSV100110331; called by muse, mutect2
- WWP1 | c.2575G>A p.G859R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337193890, COSV99616999; called by muse, mutect2
- ZNF334 | c.1584A>T p.K528N | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100749176; called by muse, mutect2
- ZNF410 | c.241A>C p.N81H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as COSV100206564; called by muse, mutect2
- COL4A5 | c.813T>A p.P271= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV100089314, COSV100090421; called by muse, mutect2
- FRMPD4 | c.2619G>A p.L873= | Silent (SNP) | VAF 5/105 reads (5%) | catalogued as rs1368263028, COSV101043812; called by muse, mutect2
- GABRB1 | c.402C>T p.V134= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99783028; called by muse, mutect2
- LPAR4 | c.501C>A p.L167= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV101425155; called by muse, mutect2
- MC5R | c.534C>A p.I178= | Silent (SNP) | VAF 23/542 reads (4%) | catalogued as COSV100229146; called by muse, mutect2
- TENM3 | c.5751C>A p.P1917= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV101305400, COSV69316065; called by muse, mutect2
- ZNF184 | c.1407T>A p.T469= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99279978; called by muse, mutect2
- ANKRD20A5P | n.156T>A | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- MGAM | c.4618+1955C>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101527707, COSV72074427; called by muse, mutect2
